Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAG2, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAG2-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; nonseminoma (ChC 100%); diameter 2 cm; tumor confined to testis; no angio-invasion; no invasion of rete testis.

Date of procurement (= date of orchidectomy):

ICD O-3

Choriorcarcinoma NOS
9100/3

Site @ Testis NOS
C62.9

9/3/7/14

pathologist

professor of pathology

Print Malignancy History		

Source: NCI Genomic Data Commons file bf883b1b-9ac8-42ec-84fb-81e266018c4e (TCGA-2G-AAG2-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).